Somatic mutation profile of tumor specimen C3L-02617-05 (aliquot CPT0229210006) from CPTAC case C3L-02617, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.9 years (23,710 days).
Specimen C3L-02617-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd6eac6a-2e72-4249-b367-d5a1b8559132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02617-31 (Blood Derived Normal), aliquot CPT0229330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d4bdc32-cc2b-4e65-9053-77c439888bd1

The open-access MAF lists 533 somatic variants for this specimen: 374 protein-altering or splice-affecting, 106 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 326, Silent 106, Intron 28, Nonsense Mutation 19, Splice Site 11, 3'UTR 8, Frame Shift Del 8, RNA 7, Frame Shift Ins 5, 5'UTR 3, 3'Flank 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>C p.X51_splice | Splice Site (SNP) | VAF 142/420 reads (34%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 71/354 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.785C>T p.T262M (on ENST00000326724 / NM_001080395.3; = p.T159M on NM_004920.2) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs774654612; called by muse, mutect2, varscan2
- AC023055.1 | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.492); catalogued as rs143656571; called by muse, mutect2, varscan2
- ACSM2A | c.317G>T p.G106V (on ENST00000219054; = p.G27V on NM_001308169.2) | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54589681; called by muse, mutect2
- ACSM2B | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 36/465 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373308064, COSV100313364; called by muse, mutect2
- ACTRT1 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as rs772248403, COSV100947591; called by muse, mutect2, varscan2
- ADAMTS12 | c.1324C>A p.R442S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61280531; called by muse, mutect2, varscan2
- ADAMTS12 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs373691746; called by muse, mutect2, varscan2
- AJAP1 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs763392397; called by muse, mutect2, varscan2
- AOC1 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268238024, COSV100710841; called by muse, mutect2, varscan2
- APC | c.2738A>G p.H913R | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs762572576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF25 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV99677967; called by muse, mutect2, varscan2
- BCHE | c.1283G>T p.C428F | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254273; called by muse, mutect2, varscan2
- C2CD5 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs564104874; called by muse, mutect2, varscan2
- CACNA1A | c.1989+1G>T p.X663_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV64210471; called by muse, mutect2, varscan2
- CACNA1G | c.2485G>A p.G829S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766342903, COSV104415863; called by muse, mutect2
- CAMK2D | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as rs1344581184; called by muse, mutect2, varscan2
- CASS4 | c.811del p.A271Lfs*24 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | catalogued as COSV64386420, COSV64386735, COSV64386803; called by mutect2, pindel*, varscan2
- CCDC25 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs374219944; called by muse, mutect2, varscan2
- CCT8L2 | c.252C>G p.H84Q | Missense Mutation (SNP) | VAF 77/313 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63463808; called by muse, mutect2, varscan2
- CDCP1 | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99944373; called by muse, mutect2, varscan2
- CFAP44 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as rs1450437694, COSV55610505; called by muse, mutect2, varscan2
- CSMD1 | c.3155C>T p.P1052L (on ENST00000520002; = p.P1051L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1388594836; called by muse, mutect2, varscan2
- CSMD3 | c.10168A>T p.T3390S (on ENST00000297405 / NM_001363185.1; = p.T3221S on NM_052900.3) | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99821379; called by muse, mutect2, varscan2
- CSMD3 | c.7460G>A p.S2487N (on ENST00000297405 / NM_001363185.1; = p.S2383N on NM_052900.3) | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV99833100; called by muse, mutect2, varscan2
- CSN1S2AP | n.216-3T>C | Splice Region (SNP) | VAF 45/120 reads (38%) | catalogued as rs1377066493; called by muse, mutect2, varscan2
- CSN2 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV61991883; called by muse, mutect2, varscan2
- DCC | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.686); catalogued as COSV59125705; called by muse, mutect2, varscan2
- DCHS1 | c.5480C>G p.A1827G | Missense Mutation (SNP) | VAF 79/448 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1252513660; called by muse, mutect2, varscan2
- DCLK3 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs756312043, COSV69363422; called by muse, varscan2
- DDX60 | c.2574+2T>C p.X858_splice | Splice Site (SNP) | VAF 26/84 reads (31%) | catalogued as COSV67095793; called by muse, mutect2, varscan2
- DENND6B | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754349882; called by muse, mutect2, varscan2
- DIPK1C | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV59726323; called by muse, mutect2, varscan2
- DIPK2A | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100237182; called by muse, mutect2, varscan2
- DMXL2 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs142770613; called by muse, mutect2, varscan2
- DNAH11 | c.5633C>T p.T1878I | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449566001; called by muse, mutect2, varscan2
- DPP10 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV69753958; called by muse, mutect2, varscan2
- DPP6 | c.2113C>A p.R705S (on ENST00000377770 / NM_001364500.2; = p.R643S on NM_001936.5) | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59604879; called by muse, mutect2, varscan2
- EPN1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 123/577 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754419293; called by muse, mutect2, varscan2
- EYS | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100677217, COSV60984721; called by mutect2, varscan2
- FAT3 | c.5255A>T p.N1752I | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53117267; called by muse, mutect2, varscan2
- FBP2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs771646420, COSV64694810; called by muse, mutect2
- FCRL5 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV62518184; called by muse, mutect2, varscan2
- FGF5 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 155/540 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs935801916; called by mutect2, varscan2
- FREM2 | c.4013C>A p.S1338Y | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs776270680, COSV54841142; called by muse, mutect2, varscan2
- GLYATL1 | c.550G>A p.D184N (on ENST00000317391 / NM_001354699.1; = p.D215N on NM_080661.4) | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as rs953629981; called by muse, mutect2, varscan2
- H2BC1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 34/198 reads (17%) | catalogued as rs1315927495; called by muse, mutect2, varscan2
- HSF2 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV63773892, COSV63774518; called by muse, mutect2, varscan2
- IGF1R | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV51304430; called by muse, mutect2, varscan2
- IL10RA | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 125/526 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1272104522; called by muse, mutect2, varscan2
- IQCJ | c.449T>G p.I150R | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV67335002; called by muse, mutect2, varscan2
- IRS4 | c.2612del p.G871Dfs*77 | Frame Shift Del (DEL) | VAF 134/343 reads (39%) | catalogued as COSV64534567; called by mutect2, pindel, varscan2
- ITPRID1 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 133/511 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as COSV60080659; called by muse, mutect2, varscan2
- JAK1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV61096883; called by muse, mutect2, varscan2
- KEAP1 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV50386938, COSV50609562, COSV99061730; called by muse, mutect2, varscan2
- KIR2DS4 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs746437419; called by muse, mutect2, varscan2
- KMT2A | c.9733C>T p.P3245S | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63290360; called by muse, mutect2, varscan2
- KMT2C | c.12667-1G>T p.X4223_splice | Splice Site (SNP) | VAF 32/149 reads (21%) | catalogued as COSV51489875; called by muse, mutect2, varscan2
- LBP | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV54139557; called by muse, mutect2, varscan2
- LRP1B | c.10267G>T p.G3423C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101260356, COSV67212758; called by muse, mutect2, varscan2
- LRP6 | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV53786736; called by muse, mutect2, varscan2
- LRRK2 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as rs766809708, COSV54157381, COSV54161437; called by muse, mutect2, varscan2
- MAP3K5 | c.3002G>T p.R1001I | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1282787956; called by muse, mutect2, varscan2
- MAP9 | c.433A>T p.K145* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100250747; called by muse, mutect2, varscan2
- MAPK15 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs577018458; called by muse, mutect2, varscan2
- MAPT | c.2456C>A p.T819K (on ENST00000262410 / NM_001377265.1; = p.T427K on NM_005910.5) | Missense Mutation (SNP) | VAF 141/533 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750991, CM043765, COSV52239106; called by muse, mutect2, varscan2
- MARS2 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 132/538 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776469200; called by muse, mutect2, varscan2
- MAST2 | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs773799954; called by muse, mutect2
- MBLAC1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 123/440 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs753136685, COSV53543214, COSV99498920; called by muse, mutect2, varscan2
- MCMDC2 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58034763; called by muse, mutect2, varscan2
- MEP1A | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 189/734 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57921717; called by muse, mutect2, varscan2
- MIEF1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100307843, COSV100307906; called by muse, mutect2, varscan2
- MRPS18B | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs200954069; called by muse, mutect2, varscan2
- MYH1 | c.2975C>A p.T992N | Missense Mutation (SNP) | VAF 119/480 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs563867561; called by muse, mutect2, varscan2
- MYOM1 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55296651; called by muse, mutect2, varscan2
- NBAS | c.4097A>G p.Y1366C | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331848647; called by muse, mutect2, varscan2
- NCOR1 | c.3671-1G>T p.X1224_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as COSV51988397; called by muse, mutect2, varscan2
- NOBOX | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as COSV56194147; called by muse, mutect2, varscan2
- NOTCH1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 94/484 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53052320, COSV99490172; called by muse, mutect2, varscan2
- NPAT | c.4197G>T p.K1399N | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV53721814; called by muse, mutect2, varscan2
- NPY1R | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56715081; called by muse, varscan2
- NPY2R | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61527135; called by muse, mutect2, varscan2
- NUP88 | c.684G>T p.R228S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs763140759; called by muse, mutect2, varscan2
- OR13G1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs1333301269, COSV100687562; called by muse, mutect2, varscan2
- OR2T1 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 33/215 reads (15%) | catalogued as COSV63542638; called by muse, mutect2, varscan2
- OR4A16 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100125091; called by muse, mutect2, varscan2
- OR4C16 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100113928, COSV58940728; called by muse, mutect2, varscan2
- OR52N2 | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57678087; called by muse, mutect2, varscan2
- OR6N1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58648637; called by muse, mutect2, varscan2
- PARD3 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs779397128; called by muse, mutect2, varscan2
- PEG3 | c.4270G>T p.G1424W | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1215749606, COSV99690876; called by muse, mutect2, varscan2
- PHOX2B | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1215649814; called by muse, mutect2, varscan2
- POTEC | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 215/969 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs772655684, COSV100743471; called by muse, mutect2, varscan2
- PPP1R1A | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99226418; called by muse, mutect2, varscan2
- PPP2R1A | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100436305; called by muse, mutect2, varscan2
- PRUNE2 | c.3944C>A p.P1315Q | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1282416116; called by muse, mutect2, varscan2
- PXDNL | c.3337del p.A1113Hfs*10 | Frame Shift Del (DEL) | VAF 38/248 reads (15%) | catalogued as COSV62497290; called by mutect2, pindel, varscan2
- RABGEF1 | c.351C>A p.F117L (on ENST00000439720 / NM_001287061.2; = p.F104L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV53161692; called by muse, mutect2, varscan2
- RASA1 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 38/166 reads (23%) | catalogued as COSV57194016; called by muse, mutect2, varscan2
- RASGRP3 | c.1875G>C p.W625C (on ENST00000402538 / NM_001349975.2; = p.W624C on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV67821732; called by muse, mutect2, varscan2
- RBM5 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61738253; called by muse, mutect2, varscan2
- RELN | c.8639C>A p.P2880Q | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1562855239; called by muse, mutect2, varscan2
- REXO1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs199974482; called by muse, varscan2
- REXO1 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs201699355, COSV50080482; called by muse, varscan2
- RYR1 | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62103479; called by muse, mutect2, varscan2
- RYR2 | c.7375G>T p.G2459W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63722412; called by muse, mutect2
- SASH1 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821435; called by muse, mutect2, varscan2
- SATB2 | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53488904; called by muse, mutect2, varscan2
- SCYL2 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs759476790; called by muse, mutect2, varscan2
- SERPINB2 | c.1013C>G p.A338G | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99449095; called by muse, mutect2, varscan2
- SIGLEC8 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as COSV58471943; called by muse, mutect2, varscan2
- SLC22A16 | c.313A>G p.K105E | Missense Mutation (SNP) | VAF 136/441 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as rs750485928; called by muse, mutect2, varscan2
- SLC26A4 | c.258T>A p.S86R | Missense Mutation (SNP) | VAF 139/549 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs756147163; called by muse, mutect2, varscan2
- SLC2A13 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785738; called by muse, mutect2, varscan2
- SPATA31D1 | c.1197A>G p.I399M | Missense Mutation (SNP) | VAF 44/467 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.184); catalogued as rs1283156464; called by muse, mutect2
- SPATA31D1 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV100782644; called by muse, mutect2, varscan2
- SPTA1 | c.4323A>T p.K1441N | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV63752765; called by muse, mutect2, varscan2
- SULT1A2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 173/513 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779279578; called by muse, mutect2, varscan2
- TAFA1 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101524442; called by muse, mutect2, varscan2
- TMEM132C | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs776599843; called by muse, mutect2, varscan2
- TP53 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 53/292 reads (18%) | catalogued as COSV52771366, COSV52826932, COSV52883452; called by muse, mutect2, varscan2
- TRAK1 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV59643516; called by muse, mutect2, varscan2
- TRHR | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100305058; called by muse, mutect2, varscan2
- UBE2NL | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 107/206 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781838711; called by muse, mutect2, varscan2
- UGT2A3 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1296378389; called by muse, mutect2, varscan2
- USH2A | c.6047C>G p.T2016R | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs750260175; called by muse, mutect2, varscan2
- WT1 | c.906G>T p.M302I | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100187968, COSV60067845; called by muse, mutect2, varscan2
- ZFHX4 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425725559, COSV99265674; called by muse, mutect2, varscan2
- ZFP37 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768318480; called by muse, mutect2, varscan2
- ZNF10 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV50216303; called by muse, mutect2, varscan2
- ZNF121 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as COSV104412353; called by muse, mutect2, varscan2
- ZNF136 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.247); catalogued as COSV59710729, COSV59711667; called by muse, mutect2, varscan2
- ZNF277 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV62463700; called by muse, mutect2, varscan2
- ZNF493 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 64/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828850; called by muse, mutect2, varscan2
- ZNF503 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277450056; called by muse, mutect2, varscan2
- ZNF572 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100073952; called by muse, mutect2, varscan2
- ZNF716 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101348596; called by muse, mutect2, varscan2
- ZNF845 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs143890862; called by muse, mutect2, varscan2
- ZZEF1 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 19/456 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as rs1159750463, COSV67556215; called by muse, mutect2
- AC105001.2 | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC244258.1 | n.497T>G | Splice Region (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2
- ACSM2B | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM4 | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGB | c.4244G>A p.G1415E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRD2 | c.2208G>T p.M736I | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.187); called by muse, varscan2
- AFDN | c.3689A>G p.Y1230C | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- AGER | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AHSP | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 131/792 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AK5 | c.1130A>G p.K377R (on ENST00000354567 / NM_174858.3; = p.K351R on NM_012093.4) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AKAP6 | c.2630G>C p.R877P | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1A2 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG1L2 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKHD1 | c.2143-1G>C p.X715_splice | Splice Site (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 99/372 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ANKRD36C | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- AP5Z1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APBB1IP | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARAP1 | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARHGAP33 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ASPM | c.9976G>C p.V3326L | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AVIL | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 104/481 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- AZIN1 | c.574A>C p.I192L | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- BAHCC1 | c.3355A>T p.T1119S | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- BRD2 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C19orf73 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CACNA2D1 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CASP8AP2 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC138 | c.1772A>T p.K591M | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CCDC50 | c.761G>T p.W254L | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCNF | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 83/506 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CHCHD6 | c.257del p.G86Vfs*63 | Frame Shift Del (DEL) | VAF 72/267 reads (27%) | called by mutect2, pindel, varscan2
- CLASRP | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 111/530 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CLCF1 | c.477_479dup p.P159_Q160insH | In Frame Ins (INS) | VAF 47/194 reads (24%) | called by mutect2, pindel, varscan2
- CLIC1 | c.176G>C p.C59S | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL19A1 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A4 | c.2671G>T p.G891C | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.1100T>G p.I367R | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COPS3 | c.866A>C p.D289A | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CORIN | c.2142_2143del p.A715Rfs*52 | Frame Shift Del (DEL) | VAF 48/428 reads (11%) | called by pindel, varscan2
- CRYBG3 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CUL7 | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 73/394 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CUX1 | c.1139C>T p.P380L (on ENST00000292535 / NM_181552.4; = p.P391L on NM_001913.5) | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CYLC1 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CYP2D7 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 170/784 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- DCHS1 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 87/417 reads (21%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3683G>T p.S1228I (on ENST00000400246; = p.S1297I on NM_014662.5) | Missense Mutation (SNP) | VAF 110/472 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- DNAAF4 | c.324A>T p.Q108H | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH5 | c.8680C>A p.P2894T | Missense Mutation (SNP) | VAF 169/568 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- DOP1A | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DPP10 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP6 | c.2330C>G p.S777C (on ENST00000377770 / NM_001364500.2; = p.S715C on NM_001936.5) | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- DPY19L4 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSTYK | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.093); called by mutect2, varscan2
- DYNC2H1 | c.9289A>T p.I3097F | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EFNB3 | c.763dup p.R255Pfs*35 | Frame Shift Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- EMCN | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); called by muse, mutect2
- EME2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 95/532 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EP300 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP400 | c.4588G>A p.G1530S | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA2 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 161/560 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHA6 | c.1417T>A p.C473S | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERV3-1 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.13); called by muse, mutect2, varscan2
- EYA4 | c.1016_1017insA p.T340Hfs*7 (on ENST00000531901 / NM_001301013.1; = p.T334Hfs*7 on NM_004100.5) | Frame Shift Ins (INS) | VAF 115/579 reads (20%) | called by mutect2, pindel, varscan2
- FAM71B | c.304T>A p.W102R | Missense Mutation (SNP) | VAF 207/433 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM90A1 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 208/908 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FANCC | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 57/670 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2
- FBN2 | c.4107T>A p.D1369E | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- FBN2 | c.2906G>A p.G969E | Missense Mutation (SNP) | VAF 108/388 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FER1L6 | c.2970C>A p.S990R | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FIGNL2 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 106/391 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GABRA1 | c.1176T>A p.S392R | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- GGA2 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GMPPB | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GNG11 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.338); called by muse, mutect2
- GNL3L | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GPX5 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GREB1L | c.1508C>A p.S503* | Nonsense Mutation (SNP) | VAF 37/274 reads (14%) | called by muse, mutect2, varscan2
- GREM1 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 114/525 reads (22%) | called by muse, mutect2, varscan2
- HCN1 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HCN1 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HDAC4 | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 171/687 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- HDGFL1 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNG | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- IGF2R | c.4173G>T p.W1391C | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-33 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 48/527 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, varscan2
- IGKV1D-39 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IGKV1D-42 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IGKV1D-43 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- IGKV6D-41 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- INSM2 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by mutect2, varscan2
- ITIH5 | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- KCNE5 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNK13 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- KDM2B | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 81/413 reads (20%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- KRT7 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 110/417 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LHFPL4 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRB1 | c.696G>T p.R232S (on ENST00000427581; = p.R196S on NM_006669.6) | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LLGL2 | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- LMTK3 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); called by muse, mutect2
- LRRC9 | c.48+2T>A p.X16_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- MACF1 | c.11192C>T p.A3731V (on ENST00000372915; = p.A1664V on NM_012090.5) | Missense Mutation (SNP) | VAF 55/303 reads (18%) | called by muse, mutect2, varscan2
- MAGED2 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MARCO | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MAST1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MMP20 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 68/254 reads (27%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, varscan2
- MPLKIP | c.288del p.S97Pfs*56 | Frame Shift Del (DEL) | VAF 73/430 reads (17%) | called by mutect2, pindel, varscan2
- MSLN | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.13007C>A p.T4336N | Missense Mutation (SNP) | VAF 114/453 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH2 | c.5423A>T p.Q1808L | Missense Mutation (SNP) | VAF 138/605 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.2579A>T p.E860V | Missense Mutation (SNP) | VAF 87/411 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYH8 | c.2140A>T p.S714C | Missense Mutation (SNP) | VAF 40/294 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MYO7A | c.6567G>C p.K2189N | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV3 | c.6581del p.R2194Kfs*4 (on ENST00000397909 / NM_001024383.2; = p.R2172Kfs*4 on NM_014903.6) | Frame Shift Del (DEL) | VAF 42/239 reads (18%) | called by mutect2, pindel, varscan2
- NBEA | c.2611G>T p.D871Y | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCKAP1L | c.2527C>A p.L843I | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NEO1 | c.4333A>G p.M1445V | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP13 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOTCH1 | c.2468-2A>T p.X823_splice | Splice Site (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- NRG3 | c.368dup p.A124Gfs*32 | Frame Shift Ins (INS) | VAF 71/278 reads (26%) | called by mutect2, pindel, varscan2
- NRG3 | c.1741A>T p.S581C (on ENST00000404547 / NM_001370084.1; = p.S557C on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NRXN1 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NTSR1 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 180/638 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NUP107 | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR10J5 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR10Q1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR14C36 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR14C36 | c.700A>T p.K234* | Nonsense Mutation (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2
- OR1E1 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- OR4A15 | c.413T>A p.V138D | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR4K13 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- OR4S1 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- OR52A1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5A2 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR7C2 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 110/511 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8D2 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAK3 | c.1667A>G p.N556S (on ENST00000262836 / NM_001324328.2; = p.N541S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.5788A>G p.I1930V | Missense Mutation (SNP) | VAF 98/463 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PKHD1 | c.3764C>T p.P1255L | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PLPPR3 | c.2089G>T p.E697* (on ENST00000520876 / NM_001270366.2; = p.E725* on NM_024888.2) | Nonsense Mutation (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- PLSCR5 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POU3F2 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 121/544 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); called by mutect2, varscan2
- PPARD | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 108/440 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PPP1R26 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP1R3B | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRAG1 | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- PRKCB | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PSTPIP1 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- PTGS1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- R3HDM1 | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAD21 | c.316_318del p.N106del | In Frame Del (DEL) | VAF 35/202 reads (17%) | called by mutect2, pindel, varscan2
- RBP3 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REG3G | c.152G>T p.C51F | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RFPL4A | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- RIN2 | c.2361G>T p.L787F (on ENST00000255006 / NM_001242581.1; = p.L738F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SATB2 | c.1741G>T p.V581L | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SCRN2 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 125/427 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCTR | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SDHAP3 | n.82G>T | Splice Region (SNP) | VAF 149/499 reads (30%) | called by muse, mutect2, varscan2
- SELP | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SEPTIN4 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SFI1 | c.1460C>T p.P487L (on ENST00000400288 / NM_001007467.3; = p.P456L on NM_014775.4) | Missense Mutation (SNP) | VAF 55/267 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGO2 | c.1387C>A p.Q463K | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIM2 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 116/536 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC1A6 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 124/492 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SLC22A15 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC24A5 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC26A7 | c.1957C>A p.H653N | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SLC5A3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9A3 | c.1504dup p.Y502Lfs*48 | Frame Shift Ins (INS) | VAF 119/474 reads (25%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1039A>T p.T347S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLX4 | c.4431del p.I1478Sfs*29 | Frame Shift Del (DEL) | VAF 51/192 reads (27%) | called by mutect2, pindel
- SMG1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPOCK2 | c.1220C>G p.A407G | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPR | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPSB4 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SREBF2 | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 110/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- STARD3NL | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- STARD9 | c.7713G>T p.R2571S | Missense Mutation (SNP) | VAF 88/335 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SULF1 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SV2A | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF5L | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 149/585 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TARS2 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- TDRD15 | c.245T>A p.M82K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TDRD6 | c.4921A>G p.I1641V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13C | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFAP4 | c.83T>A p.L28H | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TLR7 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TMEM104 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132D | c.2665C>A p.P889T | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM144 | c.625T>G p.Y209D | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNXB | c.9641C>G p.S3214W (on ENST00000647633; = p.S2967W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/521 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGJP1 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- TRIM77 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- TRIP12 | c.3926G>T p.R1309I | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TRIP12 | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRPC4 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC5 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TRPM7 | c.3116A>T p.H1039L | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TTC21A | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TTN | c.38931G>C p.W12977C (on ENST00000591111; = p.W5553C on NM_003319.4) | Missense Mutation (SNP) | VAF 51/281 reads (18%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.13352G>T p.G4451V (on ENST00000591111; = p.G4405V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTN | c.13351G>T p.G4451C (on ENST00000591111; = p.G4405C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUFM | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 241/682 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- UBE2F | c.215-2A>G p.X72_splice | Splice Site (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- UBQLN4 | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- USF3 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2
- USP14 | c.196-1G>T p.X66_splice | Splice Site (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2
- USP14 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2
- USP20 | c.2251G>T p.D751Y | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP28 | c.2299A>G p.S767G | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- VAPB | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- VCAN | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- VPS13B | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- VPS13C | c.3362G>C p.R1121T (on ENST00000644861 / NM_020821.3; = p.R1078T on NM_017684.5) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VRK3 | c.20A>T p.D7V | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VSTM2B | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WASHC2A | c.1178A>G p.E393G | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDR64 | c.1544T>C p.F515S | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- WNT9A | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- WSCD2 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.056); called by muse, mutect2
- YOD1 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- Z83844.2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBBX | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF208 | c.3523_3524insT p.G1175Vfs*14 | Frame Shift Ins (INS) | VAF 40/286 reads (14%) | called by mutect2, varscan2
- ZNF451 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 45/231 reads (19%) | called by muse, mutect2, varscan2
- ZNF738 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- ZNF835 | c.886C>A p.H296N | Missense Mutation (SNP) | VAF 129/696 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF837 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 85/477 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- AASDH | c.1815A>G p.T605= | Silent (SNP) | VAF 132/359 reads (37%) | called by muse, mutect2, varscan2
- ABCG4 | c.1848C>A p.L616= | Silent (SNP) | VAF 93/439 reads (21%) | called by muse, mutect2, varscan2
- ADSS2 | c.93G>T p.T31= | Silent (SNP) | VAF 48/369 reads (13%) | called by muse, mutect2, varscan2
- AGO1 | c.1563A>T p.P521= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- AKAP6 | c.2631G>T p.R877= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs753018110, COSV55236110; called by muse, mutect2, varscan2
- ALDH1A2 | c.252C>G p.A84= | Silent (SNP) | VAF 105/475 reads (22%) | called by muse, mutect2, varscan2
- ANGPT4 | c.648C>A p.I216= | Silent (SNP) | VAF 68/332 reads (20%) | called by muse, varscan2
- ANKRD18A | c.114C>A p.I38= | Silent (SNP) | VAF 166/677 reads (25%) | called by muse, mutect2, varscan2
- ANKRD35 | c.2529G>A p.V843= | Silent (SNP) | VAF 52/188 reads (28%) | called by muse, mutect2, varscan2
- ANKS6 | c.1305C>T p.P435= | Silent (SNP) | VAF 56/366 reads (15%) | catalogued as COSV100782372; called by muse, mutect2, varscan2
- AOAH | c.1575C>A p.P525= | Silent (SNP) | VAF 68/307 reads (22%) | catalogued as COSV51741626, COSV51751897; called by muse, mutect2, varscan2
- ARHGEF2 | c.390C>T p.L130= | Silent (SNP) | VAF 27/255 reads (11%) | called by muse, mutect2, varscan2
- ATP9B | c.609G>A p.R203= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- BAAT | c.1236A>T p.P412= | Silent (SNP) | VAF 58/299 reads (19%) | called by muse, mutect2, varscan2
- C20orf194 | c.1368C>G p.A456= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV52698886; called by muse, mutect2, varscan2
- C6 | c.2424C>T p.N808= | Silent (SNP) | VAF 52/311 reads (17%) | catalogued as rs778212785, COSV54718625; called by muse, mutect2, varscan2
- CACNA2D1 | c.558A>T p.T186= | Silent (SNP) | VAF 59/367 reads (16%) | called by muse, mutect2, varscan2
- CACNG7 | c.267C>T p.N89= | Silent (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- CDCA8 | c.57G>A p.R19= | Silent (SNP) | VAF 43/367 reads (12%) | called by muse, mutect2, varscan2
- CDH12 | c.300C>A p.T100= | Silent (SNP) | VAF 80/246 reads (33%) | catalogued as COSV66424241; called by muse, mutect2, varscan2
- CHRM5 | c.1539A>C p.R513= | Silent (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- CNR1 | c.762C>A p.G254= | Silent (SNP) | VAF 125/426 reads (29%) | catalogued as COSV62986715; called by muse, mutect2, varscan2
- COL11A1 | c.1119G>A p.L373= | Silent (SNP) | VAF 66/339 reads (19%) | catalogued as rs1434720892; called by muse, mutect2, varscan2
- COL6A1 | c.93C>T p.F31= | Silent (SNP) | VAF 90/456 reads (20%) | catalogued as rs753371577; called by muse, mutect2, varscan2
- CSPG4 | c.2319G>T p.L773= | Silent (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.39G>T p.A13= | Silent (SNP) | VAF 113/244 reads (46%) | catalogued as rs745912706, COSV100758604, COSV63581893; called by muse, mutect2, varscan2
- DCC | c.1653T>G p.P551= | Silent (SNP) | VAF 51/491 reads (10%) | called by muse, mutect2, varscan2
- DLG4 | c.1155G>T p.T385= (on ENST00000399506 / NM_001321075.3; = p.T428= on NM_001365.4) | Silent (SNP) | VAF 78/436 reads (18%) | called by muse, mutect2
- DPP10 | c.816G>T p.A272= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV59691032; called by muse, mutect2, varscan2
- EIF2B4 | c.1204C>T p.L402= (on ENST00000347454 / NM_001034116.2; = p.L401= on NM_015636.3) | Silent (SNP) | VAF 100/461 reads (22%) | catalogued as rs757012537; called by muse, mutect2, varscan2
- ESYT2 | c.2346G>T p.L782= (on ENST00000613624; = p.L706= on NM_020728.3) | Silent (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- FCGBP | c.45C>A p.T15= | Silent (SNP) | VAF 39/294 reads (13%) | catalogued as rs766654157; called by muse, mutect2, varscan2
- FCN2 | c.585G>A p.L195= | Silent (SNP) | VAF 58/315 reads (18%) | called by muse, mutect2, varscan2
- FEZF1 | c.567T>A p.P189= | Silent (SNP) | VAF 86/326 reads (26%) | called by muse, mutect2, varscan2
- GABRB2 | c.1467G>C p.R489= (on ENST00000274547; = p.R451= on NM_000813.3) | Silent (SNP) | VAF 107/249 reads (43%) | called by muse, mutect2, varscan2
- GLI4 | c.408C>T p.C136= | Silent (SNP) | VAF 74/297 reads (25%) | called by muse, mutect2, varscan2
- GLP2R | c.1467G>A p.K489= | Silent (SNP) | VAF 96/422 reads (23%) | called by muse, mutect2, varscan2
- GRID1 | c.1506C>T p.N502= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as rs201170791; called by muse, mutect2, varscan2
- H2BC10 | c.195C>A p.S65= | Silent (SNP) | VAF 95/488 reads (19%) | called by muse, mutect2, varscan2
- HEATR5B | c.5175G>T p.R1725= | Silent (SNP) | VAF 104/491 reads (21%) | called by muse, mutect2, varscan2
- HNF1A | c.741C>T p.S247= | Silent (SNP) | VAF 144/632 reads (23%) | called by muse, mutect2, varscan2
- HPCAL4 | c.153C>G p.L51= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- HUWE1 | c.5109G>T p.T1703= | Silent (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2, varscan2
- KCNA1 | c.177C>A p.P59= | Silent (SNP) | VAF 133/597 reads (22%) | called by muse, mutect2, varscan2
- KCNG3 | c.306C>T p.G102= | Silent (SNP) | VAF 139/647 reads (21%) | catalogued as rs769354044; called by muse, mutect2, varscan2
- KCNJ12 | c.1104G>T p.L368= | Silent (SNP) | VAF 78/383 reads (20%) | called by muse, mutect2, varscan2
- KDM4B | c.1149G>A p.P383= | Silent (SNP) | VAF 60/303 reads (20%) | catalogued as rs552655191, COSV50274010; called by muse, mutect2, varscan2
- KIAA1109 | c.5232G>A p.T1744= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs372039465, COSV52669583; called by muse, mutect2, varscan2
- KIR3DL1 | c.1050C>A p.I350= | Silent (SNP) | VAF 72/360 reads (20%) | catalogued as rs374398136; called by muse, mutect2, varscan2
- KLHL6 | c.1836C>T p.R612= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs776676559; called by muse, mutect2, varscan2
- KRT39 | c.681C>G p.L227= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- LDLRAD4 | c.604C>A p.R202= | Silent (SNP) | VAF 54/273 reads (20%) | called by muse, mutect2, varscan2
- LMOD2 | c.987G>T p.L329= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as rs1562951532; called by muse, mutect2, varscan2
- LRPAP1 | c.789G>T p.L263= | Silent (SNP) | VAF 77/322 reads (24%) | called by muse, mutect2, varscan2
- MAP6 | c.6G>A p.A2= | Silent (SNP) | VAF 53/275 reads (19%) | catalogued as rs1371726653; called by muse, mutect2, varscan2
- MED12L | c.5217C>T p.P1739= | Silent (SNP) | VAF 109/347 reads (31%) | catalogued as rs1317006783, COSV56391131; called by muse, mutect2, varscan2
- MUC17 | c.9492T>C p.T3164= | Silent (SNP) | VAF 74/325 reads (23%) | catalogued as rs1451527426, COSV60287676; called by muse, mutect2, varscan2
- MUC5B | c.5721C>T p.L1907= | Silent (SNP) | VAF 109/518 reads (21%) | catalogued as rs755948967; called by muse, mutect2, varscan2
- MYO5B | c.2403C>T p.H801= | Silent (SNP) | VAF 117/381 reads (31%) | catalogued as rs200132129; called by muse, mutect2, varscan2
- NEO1 | c.4332G>A p.E1444= | Silent (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
- NLRC5 | c.2472A>G p.L824= | Silent (SNP) | VAF 67/226 reads (30%) | catalogued as rs1265381969; called by muse, mutect2, varscan2
- NUP205 | c.4251G>A p.V1417= | Silent (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- OR10A6 | c.750A>G p.L250= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as rs756450019; called by muse, mutect2, varscan2
- OR2B11 | c.864T>A p.T288= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- OR2T3 | c.744C>A p.S248= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as COSV62082857; called by muse, mutect2, varscan2
- OR4S1 | c.585C>T p.L195= | Silent (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- OR51C1P | c.201C>T p.S67= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1167963481, COSV63326959; called by muse, mutect2, varscan2
- PAPPA2 | c.1611C>G p.G537= | Silent (SNP) | VAF 43/276 reads (16%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2646C>T p.G882= | Silent (SNP) | VAF 46/251 reads (18%) | catalogued as rs201893312, COSV62777230; called by muse, mutect2, varscan2
- PCDH11X | c.3210G>C p.L1070= | Silent (SNP) | VAF 115/298 reads (39%) | called by muse, mutect2, varscan2
- PCM1 | c.2928C>T p.I976= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- PCNX2 | c.4704C>T p.Y1568= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.2628G>C p.L876= | Silent (SNP) | VAF 60/281 reads (21%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.1203G>T p.L401= (on ENST00000283426; = p.L757= on NM_052909.5) | Silent (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- PODN | c.1617C>A p.A539= (on ENST00000395871; = p.A491= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV57013560; called by muse, mutect2
- PTPRS | c.1473G>T p.L491= | Silent (SNP) | VAF 80/245 reads (33%) | called by muse, mutect2, varscan2
- RASGRP3 | c.891C>T p.F297= | Silent (SNP) | VAF 65/354 reads (18%) | called by muse, mutect2, varscan2
- RELN | c.1056T>C p.N352= | Silent (SNP) | VAF 120/553 reads (22%) | called by muse, mutect2, varscan2
- RETSAT | c.153G>A p.R51= | Silent (SNP) | VAF 75/357 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.3699A>G p.Q1233= | Silent (SNP) | VAF 13/351 reads (4%) | catalogued as rs1162508252; called by muse, mutect2
- SCN1A | c.5031C>A p.L1677= (on ENST00000303395 / NM_001202435.3; = p.L1666= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/278 reads (25%) | called by muse, mutect2, varscan2
- SELENOI | c.465T>G p.V155= | Silent (SNP) | VAF 93/419 reads (22%) | called by muse, mutect2, varscan2
- SETX | c.7959C>T p.T2653= | Silent (SNP) | VAF 81/291 reads (28%) | called by muse, mutect2, varscan2
- SH3GLB2 | c.873C>T p.P291= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs371175794; called by muse, mutect2, varscan2
- SHISA9 | c.54C>A p.A18= | Silent (SNP) | VAF 208/543 reads (38%) | called by muse, mutect2, varscan2
- SHROOM2 | c.1155G>T p.P385= | Silent (SNP) | VAF 64/137 reads (47%) | called by muse, mutect2, varscan2
- SLAMF1 | c.465C>T p.N155= | Silent (SNP) | VAF 66/209 reads (32%) | catalogued as rs773729465, COSV52498867; called by muse, mutect2, varscan2
- SLC6A4 | c.1680G>T p.P560= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV55566701; called by muse, mutect2, varscan2
- SPHKAP | c.1324C>A p.R442= | Silent (SNP) | VAF 51/275 reads (19%) | catalogued as COSV60885166; called by muse, mutect2, varscan2
- SSC5D | c.3723C>G p.P1241= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, varscan2
- ST6GAL2 | c.819G>A p.A273= | Silent (SNP) | VAF 74/216 reads (34%) | catalogued as rs1437979462, COSV64527305; called by muse, mutect2, varscan2
- TBC1D9B | c.39G>T p.A13= | Silent (SNP) | VAF 126/262 reads (48%) | called by muse, mutect2, varscan2
- TCF4 | c.1374C>T p.G458= | Silent (SNP) | VAF 152/528 reads (29%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2589C>A p.V863= | Silent (SNP) | VAF 44/275 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.1500G>T p.G500= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs1235232852, COSV53034978, COSV53036761; called by muse, mutect2, varscan2
- TNIP3 | c.267G>C p.R89= | Silent (SNP) | VAF 101/398 reads (25%) | called by muse, mutect2, varscan2
- TTC25 | c.732G>T p.P244= | Silent (SNP) | VAF 107/520 reads (21%) | called by muse, mutect2, varscan2
- VPS18 | c.1938C>A p.I646= | Silent (SNP) | VAF 121/428 reads (28%) | called by muse, mutect2, varscan2
- VWA8 | c.5349G>A p.K1783= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- XRN1 | c.4674G>C p.S1558= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV53808773; called by muse, mutect2, varscan2
- ZNF202 | c.627C>T p.P209= | Silent (SNP) | VAF 63/314 reads (20%) | catalogued as rs755680190, COSV100278909; called by muse, mutect2, varscan2
- ZNF385A | c.843C>A p.S281= (on ENST00000338010 / NM_001130967.3; = p.S261= on NM_015481.3) | Silent (SNP) | VAF 87/278 reads (31%) | catalogued as rs1188714088, COSV61492960; called by muse, mutect2, varscan2
- ZNF407 | c.3153C>T p.C1051= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs376436900; ClinVar: uncertain significance; called by muse, mutect2
- ZNF497 | c.1188C>A p.R396= | Silent (SNP) | VAF 78/482 reads (16%) | catalogued as COSV54051192; called by muse, mutect2, varscan2
- ZNF544 | c.1443A>G p.T481= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- ZNF671 | c.1482C>T p.L494= | Silent (SNP) | VAF 42/273 reads (15%) | catalogued as rs1276424035; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288041del | Intron (DEL) | VAF 73/198 reads (37%) | called by mutect2, pindel, varscan2
- ADAM12 | c.2113+840C>A | Intron (SNP) | VAF 79/312 reads (25%) | called by muse, mutect2, varscan2
- AGBL1 | c.*20G>A | 3'UTR (SNP) | VAF 14/133 reads (11%) | catalogued as COSV101480063; called by muse, mutect2, varscan2
- ANKH | c.96+16G>C | Intron (SNP) | VAF 61/438 reads (14%) | called by muse, mutect2, varscan2
- ASPH | c.323-11718A>C | Intron (SNP) | VAF 26/228 reads (11%) | called by muse, mutect2, varscan2
- ATL2 | c.119-15003G>T | Intron (SNP) | VAF 10/40 reads (25%) | catalogued as rs1346686516; called by muse, mutect2, varscan2
- C6orf223 | n.363C>A | RNA (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- CHRND | c.*459T>G | 3'UTR (SNP) | VAF 46/233 reads (20%) | called by muse, mutect2, varscan2
- CNTLN | c.449+23448A>T | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, varscan2
- COL6A2 | c.2462-2492del | Intron (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7885+107G>T | Intron (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- CTNNA2 | c.102+35919C>T | Intron (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CXADRP2 | n.126G>T | RNA (SNP) | VAF 21/108 reads (19%) | called by mutect2, varscan2
- DBN1 | c.956-406C>T | Intron (SNP) | VAF 9/44 reads (20%) | catalogued as rs1178508499; called by muse, mutect2, varscan2
- DPP6 | c.*423G>T | 3'UTR (SNP) | VAF 67/252 reads (27%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009985 G>A | 5'Flank (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010742 T>A | 5'Flank (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- FAM167A | c.381+5919C>G | Intron (SNP) | VAF 37/167 reads (22%) | called by muse, mutect2, varscan2
- FGA | c.*14G>T | 3'UTR (SNP) | VAF 42/178 reads (24%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85528769 G>A | 5'Flank (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- FTH1 | chr11:61959834 T>C | 3'Flank (SNP) | VAF 68/261 reads (26%) | called by muse, mutect2, varscan2
- HBA2 | c.300+40G>A | Intron (SNP) | VAF 146/948 reads (15%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1584G>T | RNA (SNP) | VAF 134/500 reads (27%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3375C>A | Intron (SNP) | VAF 14/266 reads (5%) | catalogued as COSV55185536; called by muse, mutect2
- IGSF3 | c.1222+1402G>T | Intron (SNP) | VAF 45/229 reads (20%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701776 C>A | 3'Flank (SNP) | VAF 79/228 reads (35%) | called by muse, mutect2, varscan2
- KCNAB1 | c.275+22430G>A | Intron (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- KCNK16 | c.802+11C>A | Intron (SNP) | VAF 60/504 reads (12%) | catalogued as COSV64678724; called by muse, mutect2
- LINC01193 | n.792G>A | RNA (SNP) | VAF 62/682 reads (9%) | called by muse, mutect2
- MLIP | c.612+12057A>T | Intron (SNP) | VAF 32/160 reads (20%) | called by muse, mutect2, varscan2
- MS4A6A | c.-228G>C | 5'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- PCDHA5 | c.2352+77dup | Intron (INS) | VAF 15/104 reads (14%) | catalogued as rs781996539; called by mutect2, varscan2
- PKLR | c.-39C>G | 5'UTR (SNP) | VAF 38/258 reads (15%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.228-53587G>T | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4299A>T | Intron (SNP) | VAF 87/359 reads (24%) | catalogued as rs750094021; called by muse, mutect2, varscan2
- PPDPF | c.133+31G>T | Intron (SNP) | VAF 35/162 reads (22%) | catalogued as rs765311643; called by muse, mutect2, varscan2
- QSER1 | c.*30G>A | 3'UTR (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- RBM12B | c.-78+386G>T | Intron (SNP) | VAF 46/266 reads (17%) | catalogued as rs1394850840; called by muse, mutect2, varscan2
- SHOC2 | c.-235+17421C>T | Intron (SNP) | VAF 140/408 reads (34%) | called by muse, varscan2
- SHROOM3 | c.324-19C>G | Intron (SNP) | VAF 186/443 reads (42%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6252C>A | Intron (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- SYT14 | chr1:210163439 T>C | 3'Flank (SNP) | VAF 30/241 reads (12%) | called by muse, mutect2, varscan2
- TLCD3B | c.*3C>G | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2
- TMEM135 | c.*2207del | 3'UTR (DEL) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- TRPM4 | c.3640+28C>T | Intron (SNP) | VAF 72/374 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.34265-3033A>T | Intron (SNP) | VAF 48/269 reads (18%) | called by muse, mutect2, varscan2
- UQCRB | c.*805A>G | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as rs1333756837; called by muse, mutect2, varscan2
- Unknown | chr2:111238176 C>T | IGR (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- VN1R10P | n.650A>T | RNA (SNP) | VAF 54/268 reads (20%) | called by muse, mutect2, varscan2
- VPS51 | c.2089-110C>T | Intron (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- XIST | n.11183C>A | RNA (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- XIST | n.7489C>A | RNA (SNP) | VAF 46/82 reads (56%) | called by muse, mutect2, varscan2
- ZNF727 | c.-62C>G | 5'UTR (SNP) | VAF 53/427 reads (12%) | called by muse, mutect2, varscan2
